Gene-level copy-number profile of specimen HCM-CSHL-0839-C34-85M from HCMI case HCM-CSHL-0839-C34, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: GX; Age at diagnosis: 65.3 years (23,837 days).
Specimen HCM-CSHL-0839-C34-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 6.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 01ff000e-4916-477c-b478-b6d28320a3f2.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0839-C34-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,243 have no estimate.
https://portal.gdc.cancer.gov/files/189fb394-0ffc-4fce-8e0d-810919d1fbf1

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 12,290; copy number 2: 31,831; copy number 3: 10,374; copy number 4: 3,606; copy number 5: 232; copy number 6: 24; copy number 7: 3; copy number 8: 6; copy number 9: 13.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:8,713,311–8,713,841, 1 gene (within-gene range 0–1): AL583805.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 278 genes in 25 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:168,902,194–169,663,775, 7 genes, copy number 5 (within-gene range 4–5): LINC02082, AC092954.1, AC092954.2, LINC01997, MECOM, MECOM-AS1, RPL22P1.
- chr3:170,864,875–171,996,871, 18 genes, copy number 5: RPL22L1, EIF5A2, AC061708.1, KLF7P1, RNU1-70P, SLC2A2, TNIK, MIR569, Y_RNA, AC092919.1, AC092919.2, RNU6-348P, AC008134.1, PLD1, TMEM212-AS1, TMEM212, TMEM212-IT1, AC055714.1.
- chr3:172,425,850–173,336,965, 17 genes, copy number 5: BZW1P1, GHSR, TNFSF10, AC007919.1, LINC02068, SLC31A1P1, NCEH1, AC007919.2, RNU6-547P, AC108667.2, ECT2, SNORA72, RNU4-4P, ATP5MC1P4, AC108667.1, SPATA16, AC068759.1.
- chr3:177,294,442–177,349,166, 3 genes, copy number 5: LINC00501, ASS1P7, AC117465.1.
- chr3:177,930,758–177,959,817, 2 genes, copy number 5: AC007953.1, AC007953.2.
- chr5:38,556,765–38,671,216, 1 gene, copy number 5 (within-gene range 3–5): LIFR-AS1.
- chr5:38,682,070–38,685,126, 1 gene, copy number 5: AC010425.1.
- chr9:62,606,797–62,607,748, 1 gene, copy number 5: RAB28P2.
- chr10:23,694,746–28,408,251, 75 genes, copy number 5 (within-gene range 1–5) (broad region; genes not listed).
- chr10:28,652,630–29,736,959, 20 genes, copy number 6: RNU4ATAC6P, TPRKBP1, RNU6-1067P, BAMBI, LINC01517, AL355376.1, RNU6-270P, LINC00837, AL355376.2, RNA5SP308, RPL21P93, LYZL1, SVIL-AS1, PTCHD3P1, SVIL, MIR604, SNORD115, MIR938, CKS1BP2, RNU6-908P.
- chr10:32,446,140–32,882,874, 1 gene, copy number 8 (within-gene range 2–8): CCDC7.
- chr10:32,887,273–36,442,392, 51 genes, copy number 5–9 (within-gene range 5–10): ITGB1, AK3P5, RN7SL847P, AL365203.1, RPL7AP53, IATPR, NRP1, AL121748.1, RN7SL398P, AL353600.1, LINC02628, AL450313.1, LINC00838, RPL23P11, LINC02629, PARD3, Y_RNA, ELOBP4, RPL37P18, RPS12P16, PARD3-AS1, SS18L2P1, RNU6-847P, RNU6-193P, PRDX2P2, CUL2, MIR3611, AL392046.1, CREM, RNU7-77P, ATP6V1G1P4, AL117336.1, LINC02634, RNU6-794P, CCNY, RNU6-1167P, AL117336.2, AL603824.1, AL121749.1, GJD4, FZD8, AL121749.2, MIR4683, RPL7P37, PCAT5, LINC02630, AL355300.1, MTND5P17, MTND4P18, AL590730.1, AL590730.2.
- chr12:38,201,566–38,909,592, 8 genes, copy number 5: TUBB8P5, AC117372.1, NF1P12, Y_RNA, AC087897.1, AC087897.2, CPNE8, CPNE8-AS1.
- chr12:39,087,347–39,145,482, 1 gene, copy number 5: LINC02406.
- chr12:63,558,913–64,162,217, 13 genes, copy number 5 (within-gene range 4–5): DPY19L2, AC084357.2, AC027667.1, AC084357.3, AC084357.1, RXYLT1, RXYLT1-AS1, PABPC1P4, SRGAP1, RPL36AP41, AC079866.2, AC079866.1, AC020611.1.
- chr12:64,099,415–64,130,539, 1 gene, copy number 5 (within-gene range 4–5): AC025576.3.
- chr12:65,278,643–66,343,643, 28 genes, copy number 5: MSRB3, AC026124.1, KRT18P60, AC025419.1, AC090023.1, LINC02454, AC090023.2, PCNPP3, RPSAP52, HMGA2, AC107308.1, HMGA2-AS1, AC090673.1, MIR6074, LINC02425, RPL21P18, RNA5SP362, LLPH, AC078927.1, LLPH-DT, TMBIM4, IRAK3, RBMS1P1, MIR6502, AC078889.1, PDCL3P7, RN7SKP166, HELB.
- chr12:67,648,338–67,978,387, 6 genes, copy number 5: DYRK2, AC078777.1, LINC02421, AC022513.1, LINC01479, AC005294.1.
- chr12:68,272,443–68,451,663, 4 genes, copy number 5: MDM1, LINC02384, AC022511.1, AC008033.3.
- chr12:68,487,687–68,576,136, 3 genes, copy number 5: AC008033.2, RPSAP12, Metazoa_SRP.
- chr14:18,343,038–18,343,144, 1 gene, copy number 5: RNU6-458P.
- chr14:18,418,775–18,419,273, 1 gene, copy number 5: BNIP3P6.
- chr14:103,733,195–103,880,381, 6 genes, copy number 5 (within-gene range 3–5): PPP1R13B, AL049840.7, AL049840.1, LINC00637, AL132712.1, AL132712.2.
- chr20:8,077,251–8,968,360, 3 genes, copy number 5 (within-gene range 1–5): PLCB1, PHKBP1, PLCB1-IT1.
- chr20:13,008,972–13,368,703, 6 genes, copy number 5: SPTLC3, AL109983.1, ISM1, ISM1-AS1, AL050320.1, AL121782.1.

Autosomal genes at a single copy (total copy number 1): 11,951. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
